Somatic mutation profile of cancer-model specimen HCM-CSHL-1096-C44-85B (3D Organoid, passage 6; aliquot HCM-CSHL-1096-C44-85B-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1096-C44, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III.
Specimen HCM-CSHL-1096-C44-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e163e3c4-57bb-499c-8fea-4bd8e6fec5bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1096-C44-10A (Blood Derived Normal), aliquot HCM-CSHL-1096-C44-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee946bca-7e55-4305-bd8e-743e0c4b8109

The open-access MAF lists 3,350 somatic variants for this specimen: 2,169 protein-altering or splice-affecting, 1,044 silent, 137 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,966, Silent 1,044, Nonsense Mutation 131, Intron 87, Splice Region 36, 5'UTR 16, Splice Site 14, 3'Flank 13, Frame Shift Del 12, 3'UTR 9, RNA 6, 5'Flank 5.

Variants (750 of 3,350; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14A | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 106/303 reads (35%) | catalogued as rs549556142, COSV60556075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748222885; called by muse, mutect2, varscan2
- AARS1 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.08); catalogued as rs777776042; called by muse, mutect2, varscan2
- ABCA12 | c.3901G>A p.A1301T (on ENST00000272895 / NM_173076.3; = p.A983T on NM_015657.3) | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs141932167; called by muse, mutect2, varscan2
- ABCA13 | c.6856C>T p.L2286F | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs1230733061, COSV101330071; called by muse, mutect2, varscan2
- ABCA13 | c.11410G>A p.E3804K | Missense Mutation (SNP) | VAF 78/339 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as COSV71291807; called by muse, mutect2, varscan2
- ABCC3 | c.4465G>A p.D1489N | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53325585, COSV99559442; called by muse, mutect2, varscan2
- ABCC9 | c.3131G>A p.G1044E | Missense Mutation (SNP) | VAF 130/297 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV53965917; called by muse, mutect2, varscan2
- ABCC9 | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 100/242 reads (41%) | catalogued as COSV99038986; called by muse, mutect2, varscan2
- ABI3BP | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 218/364 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs866268966, COSV52543037, COSV52549187; called by muse, mutect2, varscan2
- ABTB1 | c.444G>A p.W148* (on ENST00000232744 / NM_172027.3; = p.W6* on NM_032548.3) | Nonsense Mutation (SNP) | VAF 148/430 reads (34%) | catalogued as COSV99229842; called by muse, mutect2, varscan2
- AC015802.6 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1294915911; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 211/665 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACLY | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 242/562 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV61250753; called by muse, mutect2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACSM1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54640781; called by muse, mutect2, varscan2
- ACSM3 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 186/280 reads (66%) | catalogued as rs766653580; called by muse, mutect2, varscan2
- ACSM4 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 157/312 reads (50%) | catalogued as rs1565750910; called by muse, mutect2, varscan2
- ACTN2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as rs1281750006; called by muse, mutect2
- ADAM7 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 131/172 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911395416, COSV51535792; called by muse, mutect2, varscan2
- ADAMTS15 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 261/352 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372024440, COSV54503139; called by muse, mutect2, varscan2
- ADAMTS8 | c.1205C>G p.T402R | Missense Mutation (SNP) | VAF 118/572 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs758545232; called by muse, mutect2, varscan2
- ADCY5 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV59203688; called by muse, mutect2, varscan2
- ADCY7 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 158/236 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs766450001; called by muse, mutect2, varscan2
- ADGB | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1322224854; called by muse, mutect2, varscan2
- ADGRB3 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 230/361 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1304575172, COSV101000369; called by muse, mutect2, varscan2
- ADGRF3 | c.478C>T p.L160F (on ENST00000311519 / NM_001145168.1; = p.L101F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 478/480 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs1438414371; called by muse, mutect2, varscan2
- ADGRG5 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748490296; called by muse, mutect2, varscan2
- ADGRV1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV67995151; called by muse, mutect2, varscan2
- ADGRV1 | c.10214G>A p.R3405Q | Missense Mutation (SNP) | VAF 171/262 reads (65%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs727504728, COSV67985287, COSV67992259; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADH1B | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100520801, COSV59294995; called by muse, mutect2, varscan2
- AFAP1L1 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 201/288 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1339162672, COSV57045793; called by muse, mutect2, varscan2
- AFDN | c.4704G>C p.K1568N | Missense Mutation (SNP) | VAF 126/599 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60046144; called by muse, mutect2, varscan2
- AGAP4 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 221/428 reads (52%) | catalogued as rs1227592532; called by muse, mutect2, varscan2
- AGBL3 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV51951212; called by muse, mutect2, varscan2
- AGGF1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1171715592, COSV57231513; called by muse, mutect2, varscan2
- AHCTF1 | c.3187C>T p.R1063* (on ENST00000366508; = p.R1037* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 124/202 reads (61%) | catalogued as COSV100404532; called by muse, varscan2
- AHDC1 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 404/582 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as rs767594160; called by muse, varscan2
- AHNAK | c.11828C>T p.P3943L | Missense Mutation (SNP) | VAF 124/564 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV57224607; called by muse, mutect2, varscan2
- AKAP13 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100773163; called by muse, mutect2, varscan2
- AKAP6 | c.6370G>A p.E2124K | Missense Mutation (SNP) | VAF 184/291 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs926646241, COSV55204844; called by muse, mutect2, varscan2
- AKR1B15 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 194/502 reads (39%) | catalogued as COSV71151468; called by muse, mutect2, varscan2
- AL592490.1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 200/285 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1365085308; called by muse, mutect2, varscan2
- ALDH1L1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 148/503 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as rs868384519; called by muse, mutect2, varscan2
- ALDH1L2 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 172/353 reads (49%) | catalogued as rs759837940; called by muse, mutect2, varscan2
- ALG9 | c.1798C>T p.R600W (on ENST00000614444 / NM_001352418.1; = p.R607W on NM_024740.2) | Missense Mutation (SNP) | VAF 181/261 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs781849410; called by muse, mutect2, varscan2
- ALK | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 408/409 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as rs200364883, COSV66561092, COSV66594696; called by muse, mutect2, varscan2
- ALX4 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 116/582 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766809146; called by muse, mutect2, varscan2
- AMPH | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 312/640 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216062938; called by muse, mutect2
- AMPH | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 254/572 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.116); catalogued as rs748822925, COSV57747270; called by muse, varscan2
- ANK2 | c.7585G>A p.E2529K | Missense Mutation (SNP) | VAF 253/408 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1564024760; called by muse, mutect2, varscan2
- ANKRD30A | c.219G>A p.K73= (on ENST00000611781; = p.K17= on NM_052997.2) | Splice Region (SNP) | VAF 74/259 reads (29%) | catalogued as rs756091623, COSV64611479; called by muse, mutect2, varscan2
- ANKRD30B | c.2879G>A p.R960K | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as rs1362493646; called by muse, mutect2, varscan2
- ANKS1A | c.735G>A p.T245= | Splice Region (SNP) | VAF 326/529 reads (62%) | catalogued as rs1273506779; called by muse, mutect2, varscan2
- ANKS4B | c.165-1G>A p.X55_splice | Splice Site (SNP) | VAF 54/180 reads (30%) | catalogued as COSV61140218; called by muse, varscan2
- ANKS6 | c.2142G>A p.K714= | Splice Region (SNP) | VAF 297/297 reads (100%) | catalogued as CM1514718; called by muse, mutect2, varscan2
- APAF1 | c.2172C>G p.F724L (on ENST00000551964 / NM_181861.2; = p.F713L on NM_001160.3) | Missense Mutation (SNP) | VAF 170/250 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100244362; called by muse, mutect2, varscan2
- APBB1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1020056519, COSV54981054; called by muse, mutect2, varscan2
- APC | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV57333109, COSV57383671, COSV57401345; called by muse, mutect2, varscan2
- APLF | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 220/222 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757332939; called by muse, mutect2, varscan2
- APLP1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 365/581 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs867658228; called by muse, mutect2, varscan2
- AQP7 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 929/930 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs774564666; called by muse, mutect2, varscan2
- ARFGEF3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 352/592 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs747221894; called by muse, mutect2, varscan2
- ARHGAP20 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 101/487 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs748103380, COSV52813249; called by muse, mutect2, varscan2
- ARHGEF5 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 125/710 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1261428908; called by muse, mutect2, varscan2
- ARID1B | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 373/680 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as COSV51661164; called by muse, mutect2, varscan2
- ARID2 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 192/402 reads (48%) | catalogued as COSV57603793, COSV57616521; called by muse, varscan2
- ARMC2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 248/457 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs751335272; called by muse, mutect2, varscan2
- ASB17 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.956); catalogued as rs755393836, COSV52410026; called by muse, mutect2, varscan2
- ASXL1 | c.4174C>T p.P1392S | Missense Mutation (SNP) | VAF 312/885 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as rs368624471; called by muse, mutect2, varscan2
- ATF2 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 306/308 reads (99%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs139861769; called by muse, mutect2, varscan2
- ATF6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 66/173 reads (38%) | catalogued as rs146640460, COSV63408740; called by muse, mutect2, varscan2
- ATP10B | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV59145953, COSV59161136; called by muse, mutect2, varscan2
- ATP11B | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV60028937; called by muse, mutect2, varscan2
- ATRNL1 | c.3286C>T p.R1096C | Missense Mutation (SNP) | VAF 83/119 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58104610; called by muse, mutect2, varscan2
- AUTS2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 303/576 reads (53%) | catalogued as CM145747, COSV61395949; called by muse, mutect2, varscan2
- AXDND1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs924042947, COSV62644892; called by muse, mutect2, varscan2
- B4GALT2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs145863808; called by muse, mutect2, varscan2
- BARHL1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 345/345 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV55037435; called by muse, mutect2, varscan2
- BAZ1A | c.4616C>T p.P1539L | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV62411014; called by muse, mutect2, varscan2
- BBS12 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 94/159 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV58561890; called by muse, mutect2, varscan2
- BCL11B | c.1159C>T p.P387S (on ENST00000357195 / NM_001282237.2; = p.P316S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 244/854 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs983772447; called by muse, mutect2, varscan2
- BDP1 | c.3125G>A p.R1042K | Missense Mutation (SNP) | VAF 321/510 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1431749917; called by muse, mutect2, varscan2
- BFAR | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 322/489 reads (66%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs759302751; called by muse, mutect2, varscan2
- BIN1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1485180311; called by muse, mutect2, varscan2
- BLM | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.328); catalogued as rs1451973495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP5 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 79/485 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100895786; called by muse, mutect2, varscan2
- BPNT1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 363/526 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1453864571; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAP | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 258/506 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs770360667, COSV59537000; called by muse, mutect2, varscan2
- BRD7 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs773167671; called by muse, mutect2, varscan2
- BRWD1 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 191/434 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs751937145; called by muse, mutect2, varscan2
- BTN3A1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 131/644 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1399763366; called by muse, mutect2, varscan2
- C1QTNF9B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 208/586 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.318); catalogued as rs770234246, COSV101158632; called by muse, mutect2, varscan2
- C3orf20 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 110/509 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751924416, COSV53784722; called by muse, mutect2, varscan2
- C6 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs147459672; called by muse, mutect2, varscan2
- C6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54706408; called by muse, mutect2, varscan2
- C6orf118 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 288/478 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs773384059; called by muse, mutect2, varscan2
- C6orf52 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 77/503 reads (15%) | catalogued as COSV99035885; called by muse, mutect2, varscan2
- C8B | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs766363026; called by muse, mutect2, varscan2
- C8orf34 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs867335537, COSV57400749, COSV57402183; called by muse, mutect2, varscan2
- CACNA1E | c.5828C>T p.P1943L | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100704535; called by muse, mutect2, varscan2
- CADPS | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV51865675; called by muse, mutect2, varscan2
- CALCR | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs972946; called by muse, mutect2, varscan2
- CALR | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 152/318 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs199565419, COSV57134466; called by muse, mutect2, varscan2
- CAMK2B | c.699C>T p.F233= | Splice Region (SNP) | VAF 177/355 reads (50%) | catalogued as rs747807389; called by muse, mutect2, varscan2
- CAMSAP2 | c.3325C>T p.P1109S (on ENST00000236925 / NM_001297707.2; = p.P1098S on NM_203459.3) | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1269671236; called by muse, mutect2, varscan2
- CAPN9 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 257/417 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1279806414, COSV55230247; called by muse, mutect2, varscan2
- CARM1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1186100976; called by muse, mutect2, varscan2
- CARS2 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 273/432 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs902904499; called by muse, mutect2, varscan2
- CASP8 | c.743G>A p.R248Q (on ENST00000432109 / NM_033355.3; = p.R265Q on NM_001228.4) | Missense Mutation (SNP) | VAF 369/371 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs764461240, COSV51862120, COSV51862224; called by muse, mutect2, varscan2
- CCDC102B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV60154758; called by muse, mutect2, varscan2
- CCDC116 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 628/631 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as rs774973048; called by muse, mutect2, varscan2
- CCDC166 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 1151/1414 reads (81%) | SIFT tolerated (0.63); PolyPhen benign (0.037); catalogued as rs1351463313; called by muse, mutect2, varscan2
- CCDC88B | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 447/645 reads (69%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.06); catalogued as rs1465161324, COSV57267650; called by muse, mutect2, varscan2
- CCDC88B | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 384/518 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1284480741; called by muse, mutect2, varscan2
- CCKBR | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 191/731 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs140350741; called by muse, mutect2, varscan2
- CCS | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs1368654282; called by muse, mutect2, varscan2
- CD22 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 137/458 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV50060768; called by muse, mutect2, varscan2
- CD22 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 98/315 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.401); catalogued as rs1248392204; called by muse, mutect2, varscan2
- CD226 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV54614698; called by muse, mutect2, varscan2
- CD84 | c.1006C>T p.P336S (on ENST00000311224 / NM_001184879.2; = p.P319S on NM_003874.4) | Missense Mutation (SNP) | VAF 205/325 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs749408655, COSV60870906; called by muse, mutect2, varscan2
- CDH10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV52576110; called by muse, mutect2, varscan2
- CDH18 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 120/333 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.698); catalogued as rs1176383452; called by muse, varscan2
- CDH19 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749750028; called by muse, varscan2
- CDH19 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762319450; called by muse, mutect2, varscan2
- CDH19 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767929716; called by muse, mutect2, varscan2
- CDKN2A | c.169del p.A57Pfs*89 | Frame Shift Del (DEL) | VAF 1120/1178 reads (95%) | catalogued as COSV58685036, COSV58685696, COSV58703844; called by mutect2, pindel*, varscan2
- CDR1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 355/355 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV65164514; called by muse, mutect2, varscan2
- CDX1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762108876; called by muse, mutect2, varscan2
- CENPE | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs765562848; called by muse, mutect2, varscan2
- CENPT | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99534995; called by muse, mutect2, varscan2
- CENPT | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs761279209; called by muse, mutect2, varscan2
- CEP164 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 85/409 reads (21%) | catalogued as rs963142616; called by muse, mutect2, varscan2
- CEP250 | c.5408G>A p.S1803N | Missense Mutation (SNP) | VAF 365/657 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as rs765875340; called by muse, mutect2, varscan2
- CES1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 145/954 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62085963; called by muse, mutect2, varscan2
- CFAP54 | c.4286C>T p.P1429L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs747467466; called by muse, mutect2, varscan2
- CFAP61 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 272/938 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs746693168; called by muse, mutect2
- CFH | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV66414666; called by muse, mutect2, varscan2
- CFHR5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 102/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56825945; called by muse, mutect2, varscan2
- CHD8 | c.5711C>G p.P1904R (on ENST00000646647 / NM_001170629.2; = p.P1625R on NM_020920.4) | Missense Mutation (SNP) | VAF 130/378 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs750353323; called by muse, mutect2, varscan2
- CHL1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs150837773; called by muse, mutect2, varscan2
- CHL1 | c.2612C>T p.S871L (on ENST00000397491 / NM_001253387.1; = p.S887L on NM_006614.4) | Missense Mutation (SNP) | VAF 196/248 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs868175740; called by muse, mutect2, varscan2
- CHRM2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 267/491 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.411); catalogued as COSV57776938; called by muse, mutect2, varscan2
- CHRNA7 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 383/1182 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs759662036; called by muse, mutect2, varscan2
- CHST5 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 160/549 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1301529083, COSV60340797; called by muse, mutect2, varscan2
- CHST8 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 175/578 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs1344956844, COSV52857919; called by muse, mutect2, varscan2
- CIART | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 231/364 reads (63%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.207); catalogued as rs782171605, COSV51745415; called by muse, mutect2, varscan2
- CILP2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52274165; called by muse, mutect2, varscan2
- CLCN3 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 164/248 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV61627367; called by muse, mutect2, varscan2
- CLSTN3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 107/533 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1393171977, COSV56934143; called by muse, mutect2, varscan2
- CLVS2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 174/328 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.328); catalogued as COSV51565713; called by muse, mutect2, varscan2
- CNBD1 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV73074119; called by muse, mutect2, varscan2
- CNGA4 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 109/488 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs202030466; called by muse, mutect2, varscan2
- CNST | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 156/251 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs542973916; called by muse, mutect2, varscan2
- CNTN3 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 265/401 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55164503, COSV55171000; called by muse, mutect2, varscan2
- CNTN3 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 206/304 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV55163859; called by muse, mutect2, varscan2
- CNTN4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1393573209, COSV61867862; called by muse, mutect2, varscan2
- CNTN6 | c.1369T>A p.F457I | Missense Mutation (SNP) | VAF 131/176 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV63182611; called by muse, mutect2, varscan2
- CNTNAP4 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs556620057, COSV56680869; called by muse, mutect2
- CNTNAP4 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 188/320 reads (59%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.951); catalogued as rs189024291; called by muse, mutect2, varscan2
- COG3 | c.1931-1G>A p.X644_splice | Splice Site (SNP) | VAF 48/200 reads (24%) | catalogued as COSV100596533; called by muse, mutect2, varscan2
- COL10A1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 257/623 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368764774, COSV54574886; called by muse, mutect2, varscan2
- COL11A1 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 233/456 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs757495447, COSV62200202; called by muse, mutect2, varscan2
- COL11A1 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 231/450 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV62172860; called by muse, mutect2, varscan2
- COL11A1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV62189442; called by muse, mutect2, varscan2
- COL12A1 | c.5674C>T p.P1892S | Missense Mutation (SNP) | VAF 198/389 reads (51%) | SIFT tolerated (0.86); PolyPhen benign (0.108); catalogued as COSV100486447; called by muse, mutect2, varscan2
- COL17A1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 215/677 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1222426416; called by muse, mutect2, varscan2
- COL22A1 | c.4736G>A p.G1579E | Missense Mutation (SNP) | VAF 456/592 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281393; called by muse, mutect2, varscan2
- COL22A1 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 399/516 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs374559245; called by muse, mutect2, varscan2
- COL22A1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 96/460 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57345550; called by muse, mutect2, varscan2
- COL24A1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65310610; called by muse, mutect2, varscan2
- COL3A1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV58585428; called by muse, mutect2, varscan2
- COL6A3 | c.6511G>A p.G2171R | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55090010, COSV99797982; called by muse, mutect2, varscan2
- COL6A5 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.765); catalogued as rs548996198; called by muse, mutect2, varscan2
- COL6A6 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369345663; called by muse, mutect2, varscan2
- COL8A1 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 329/511 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246699124; called by muse, mutect2, varscan2
- COL9A3 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 308/792 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406567877, COSV100673303; called by muse, mutect2, varscan2
- COL9A3 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 214/649 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.516); catalogued as rs775950914; called by muse, mutect2, varscan2
- COLEC10 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60521982; called by muse, mutect2, varscan2
- COX4I2 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 198/718 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65781852; called by muse, mutect2, varscan2
- CPED1 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750787348, COSV100120924; called by muse, mutect2, varscan2
- CRAMP1 | c.2488C>T p.L830F | Missense Mutation (SNP) | VAF 219/352 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1352985988, COSV51962249; called by muse, mutect2, varscan2
- CREB3L3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904897637; called by muse, mutect2, varscan2
- CRISPLD1 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 105/590 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs751295545, COSV104384923; called by muse, mutect2, varscan2
- CRTAC1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 151/428 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as rs755231036; called by muse, mutect2, varscan2
- CSF1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 265/428 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV60033826, COSV60034186; called by muse, mutect2, varscan2
- CSF3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 310/674 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV56641182; called by muse, mutect2, varscan2
- CSMD1 | c.10081G>T p.G3361W (on ENST00000520002; = p.G3360W on NM_033225.6) | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358051627; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 235/316 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD1 | c.5864C>T p.S1955F (on ENST00000520002; = p.S1954F on NM_033225.6) | Missense Mutation (SNP) | VAF 72/448 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1384100478; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSMD2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 216/366 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355609119, COSV53911378; called by muse, mutect2, varscan2
- CSMD3 | c.10807C>A p.Q3603K (on ENST00000297405 / NM_001363185.1; = p.Q3434K on NM_052900.3) | Missense Mutation (SNP) | VAF 131/168 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV52117656; called by muse, mutect2, varscan2
- CSMD3 | c.10714G>A p.E3572K (on ENST00000297405 / NM_001363185.1; = p.E3403K on NM_052900.3) | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs1471973275, COSV52139070, COSV52186456; called by muse, mutect2, varscan2
- CSMD3 | c.7574T>C p.L2525P (on ENST00000297405 / NM_001363185.1; = p.L2421P on NM_052900.3) | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52174766; called by muse, mutect2, varscan2
- CSMD3 | c.6652G>A p.A2218T (on ENST00000297405 / NM_001363185.1; = p.A2114T on NM_052900.3) | Missense Mutation (SNP) | VAF 145/180 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs778364128, COSV52184767; called by muse, mutect2, varscan2
- CSMD3 | c.6212G>A p.G2071E (on ENST00000297405 / NM_001363185.1; = p.G1967E on NM_052900.3) | Missense Mutation (SNP) | VAF 168/212 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV52259090, COSV52349990; called by muse, mutect2, varscan2
- CSMD3 | c.4624G>A p.D1542N (on ENST00000297405 / NM_001363185.1; = p.D1438N on NM_052900.3) | Missense Mutation (SNP) | VAF 124/586 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV52349455; called by muse, mutect2, varscan2
- CSMD3 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 111/570 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99033609; called by muse, mutect2, varscan2
- CSNK1G2 | c.771C>T p.A257= | Splice Region (SNP) | VAF 180/348 reads (52%) | catalogued as rs747657577; called by muse, varscan2
- CT47B1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 526/530 reads (99%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs200243472, COSV64890855; called by muse, varscan2
- CTNNA2 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 266/267 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV63592326; called by muse, varscan2
- CTNND2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104394439; called by muse, mutect2, varscan2
- CTSW | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1194706208; called by muse, mutect2, varscan2
- CUL9 | c.5875C>T p.P1959S | Missense Mutation (SNP) | VAF 408/657 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs1464121436; called by muse, mutect2, varscan2
- CWC27 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 45/81 reads (56%) | catalogued as rs747744168, COSV66885021; called by muse, mutect2, varscan2
- CYP2C19 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV64907127; called by muse, mutect2, varscan2
- CYP2C9 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 179/271 reads (66%) | catalogued as rs749575375; called by muse, mutect2, varscan2
- CYP46A1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 133/473 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV55896320; called by muse, mutect2, varscan2
- DAAM2 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 323/534 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs369945548; called by muse, mutect2, varscan2
- DACH1 | c.1670G>A p.G557E (on ENST00000619232 / NM_001366712.1; = p.G505E on NM_080759.6) | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.726); catalogued as rs778155363; called by muse, mutect2, varscan2
- DAGLA | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 100/488 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99944640; called by muse, mutect2, varscan2
- DAGLA | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 564/762 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57198417; called by muse, mutect2, varscan2
- DCAF4L1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 147/213 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV60786564; called by muse, mutect2, varscan2
- DCLK1 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55212525; called by muse, mutect2, varscan2
- DDR2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 247/381 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV63369482; called by muse, mutect2, varscan2
- DDX10 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.247); catalogued as rs147675016; called by muse, mutect2, varscan2
- DGKZ | c.3250C>T p.R1084W (on ENST00000454345 / NM_001105540.2; = p.R896W on NM_003646.4) | Missense Mutation (SNP) | VAF 331/449 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs759458475; called by muse, mutect2, varscan2
- DHX30 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 120/582 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as rs370921443; called by muse, mutect2, varscan2
- DKK2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53398164; called by muse, mutect2, varscan2
- DLEC1 | c.5083G>A p.E1695K | Missense Mutation (SNP) | VAF 529/698 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as rs1330391645; called by muse, mutect2, varscan2
- DLL3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 109/187 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1346497180, CD031037; called by muse, mutect2, varscan2
- DMBT1 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 140/535 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs763575906; called by muse, mutect2, varscan2
- DMBX1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 121/414 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV63601959; called by muse, mutect2, varscan2
- DMD | c.7712G>A p.R2571Q | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371588290, COSV58921022; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.5015C>T p.P1672L | Missense Mutation (SNP) | VAF 121/578 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs370691776; called by muse, mutect2, varscan2
- DNAH10 | c.10648G>A p.D3550N (on ENST00000409039; = p.D3489N on NM_207437.3) | Missense Mutation (SNP) | VAF 312/714 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68988348; called by muse, mutect2, varscan2
- DNAH3 | c.9346G>A p.E3116K | Missense Mutation (SNP) | VAF 149/425 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550653; called by muse, mutect2, varscan2
- DNAH6 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 111/111 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs760148643; called by muse, mutect2, varscan2
- DNAH8 | c.6650C>T p.S2217F | Missense Mutation (SNP) | VAF 81/469 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547661, COSV59431846; called by muse, mutect2, varscan2
- DNAH9 | c.12926G>A p.R4309Q | Missense Mutation (SNP) | VAF 233/472 reads (49%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.509); catalogued as rs147022425; called by muse, mutect2, varscan2
- DNAJB14 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 122/353 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1486598557; called by muse, mutect2, varscan2
- DNM2 | c.2390C>T p.P797L (on ENST00000355667 / NM_001005360.3; = p.P793L on NM_004945.3) | Missense Mutation (SNP) | VAF 169/385 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV53035179; called by muse, mutect2, varscan2
- DNMBP | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 240/350 reads (69%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs756556798; called by muse, mutect2, varscan2
- DOCK3 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.043); catalogued as COSV56554918; called by muse, mutect2, varscan2
- DOCK4 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs374007614, COSV101455429; called by muse, mutect2, varscan2
- DOCK7 | c.3679C>T p.P1227S (on ENST00000635253 / NM_001367561.1; = p.P1196S on NM_033407.3) | Missense Mutation (SNP) | VAF 222/433 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs756746649; called by muse, mutect2, varscan2
- DPPA4 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 185/271 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.424); catalogued as COSV59512541; called by muse, mutect2, varscan2
- DPYD | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64609964; called by muse, mutect2, varscan2
- DPYSL2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 434/582 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100233688, COSV60784114; called by muse, mutect2, varscan2
- DRICH1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 303/303 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs778926109; called by muse, mutect2, varscan2
- DSCAM | c.3960G>A p.M1320I | Missense Mutation (SNP) | VAF 119/261 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV68026889; called by muse, mutect2, varscan2
- DSEL | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs745871525, COSV100025833; called by muse, mutect2, varscan2
- DST | c.17476G>A p.A5826T (on ENST00000361203 / NM_001374722.1; = p.A3523T on NM_015548.5) | Missense Mutation (SNP) | VAF 204/560 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55017871; called by muse, mutect2, varscan2
- DTHD1 | c.1669C>T p.R557* (on ENST00000456874; = p.R392* on NM_001136536.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 234/342 reads (68%) | catalogued as rs750691784, COSV62629499; called by muse, mutect2, varscan2
- DTL | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs755533677, COSV100877238; called by muse, mutect2, varscan2
- DVL1 | c.1592C>T p.P531L (on ENST00000378888 / NM_001330311.2; = p.P506L on NM_004421.3) | Missense Mutation (SNP) | VAF 487/763 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs199505104, CD152692; called by muse, mutect2, varscan2
- DVL1 | c.1591C>T p.P531S (on ENST00000378888 / NM_001330311.2; = p.P506S on NM_004421.3) | Missense Mutation (SNP) | VAF 486/762 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs751211931; called by muse, mutect2, varscan2
- DYRK3 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 126/465 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65605442; called by muse, mutect2, varscan2
- DZIP3 | c.2818G>A p.G940R | Missense Mutation (SNP) | VAF 118/197 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974059823; called by muse, mutect2, varscan2
- EBF2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 103/592 reads (17%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as rs1279526954; called by muse, mutect2, varscan2
- ECM1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 144/454 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.196); catalogued as rs781194369; called by muse, mutect2, varscan2
- ECT2 | c.2668C>T p.P890S (on ENST00000392692 / NM_001349098.2; = p.P859S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV99222014; called by muse, mutect2, varscan2
- EDEM1 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56582634; called by muse, mutect2, varscan2
- EDIL3 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896466; called by muse, mutect2, varscan2
- EDIL3 | c.922C>G p.R308G | Missense Mutation (SNP) | VAF 155/257 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56898991; called by muse, mutect2, varscan2
- EFHB | c.2390G>A p.W797* | Nonsense Mutation (SNP) | VAF 71/342 reads (21%) | catalogued as COSV99859461, COSV99860046; called by muse, mutect2, varscan2
- EFR3B | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 527/527 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67841722; called by muse, mutect2, varscan2
- EGFLAM | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59295524; called by muse, mutect2, varscan2
- EIF4E | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1407830526; called by muse, mutect2, varscan2
- EIF4G1 | c.1639C>T p.Q547* (on ENST00000346169 / NM_198241.3; = p.Q351* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 241/360 reads (67%) | catalogued as COSV59989123; called by muse, mutect2, varscan2
- ELAPOR2 | c.1358C>T p.S453F (on ENST00000450689 / NM_001142749.3; = p.S286F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/296 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV51891340; called by muse, mutect2, varscan2
- ELK4 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 442/588 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs372605541, COSV56985984; called by muse, mutect2, varscan2
- ELL2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 137/392 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52984247; called by muse, mutect2, varscan2
- ELMOD1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 264/380 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56194575; called by muse, mutect2, varscan2
- ELP5 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 426/427 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs745732933; called by muse, mutect2, varscan2
- EMB | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57483692; called by muse, mutect2, varscan2
- EPHA6 | c.2083C>T p.P695S (on ENST00000389672 / NM_001080448.3; = p.P87S on NM_173655.4) | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV101063221, COSV67561294; called by muse, mutect2, varscan2
- EPHA7 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 136/254 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV65191590; called by muse, mutect2, varscan2
- EPSTI1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100553286; called by muse, mutect2, varscan2
- EPX | c.1980A>C p.K660N | Missense Mutation (SNP) | VAF 204/462 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1307559689; called by muse, mutect2, varscan2
- ERAP1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 280/479 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV57085290; called by muse, mutect2
- ERC2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 416/573 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750451019, COSV55603699; called by muse, mutect2, varscan2
- ERF | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 287/493 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV55896028; called by muse, mutect2, varscan2
- ERICH3 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 323/632 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV58613319; called by muse, mutect2, varscan2
- ERICH6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 176/634 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV55799082; called by mutect2, varscan2
- ESR2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50834637; called by muse, mutect2, varscan2
- ESR2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261390478; called by muse, mutect2, varscan2
- ETV1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 225/497 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.609); catalogued as COSV54143755; called by muse, mutect2, varscan2
- EXOC3L2 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 141/370 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs751543675, COSV52972165; called by muse, mutect2, varscan2
- EXOSC9 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 166/303 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696713; called by muse, mutect2, varscan2
- EYA1 | c.155C>A p.T52K | Missense Mutation (SNP) | VAF 69/439 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV58170234; called by muse, mutect2, varscan2
- EYS | c.3941G>A p.R1314K | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1330067403; called by muse, mutect2, varscan2
- EYS | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372391247, COSV60982434; called by muse, mutect2, varscan2
- EYS | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as CM157893, COSV60997369, COSV60998112; called by muse, mutect2, varscan2
- EZH1 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 236/501 reads (47%) | catalogued as COSV70548551; called by muse, mutect2, varscan2
- F13A1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99343676; called by muse, mutect2, varscan2
- FAM120A | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs138634055; called by muse, mutect2, varscan2
- FAM133A | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 158/160 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100220696; called by muse, mutect2, varscan2
- FAM135B | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 95/581 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1563691297, COSV52715866; called by muse, mutect2, varscan2
- FAM171A1 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 231/396 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754969038; called by muse, mutect2, varscan2
- FAM171A1 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 177/517 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV65313958; called by muse, mutect2, varscan2
- FAM209B | c.250-1G>A p.X84_splice | Splice Site (SNP) | VAF 199/326 reads (61%) | catalogued as rs1201858087; called by muse, mutect2, varscan2
- FAM210A | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 140/208 reads (67%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs779671314, COSV59183726; called by muse, mutect2, varscan2
- FAM47A | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 228/230 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs770302558, COSV60493694; called by muse, mutect2, varscan2
- FARSA | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466031326, COSV100108877, COSV58905581; called by muse, mutect2, varscan2
- FASN | c.7394C>T p.S2465F | Missense Mutation (SNP) | VAF 256/396 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60761105; called by muse, mutect2, varscan2
- FAT1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 204/322 reads (63%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.998); catalogued as COSV71675893; called by muse, varscan2
- FAT1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018407179, COSV71671881, COSV71673671; called by muse, varscan2
- FAT4 | c.4813G>A p.D1605N | Missense Mutation (SNP) | VAF 237/361 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs773127644; called by muse, mutect2, varscan2
- FAT4 | c.14578G>A p.E4860K | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58713688; called by muse, mutect2, varscan2
- FBN1 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 247/368 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV57310001; called by muse, mutect2, varscan2
- FBN2 | c.8686C>A p.L2896I | Missense Mutation (SNP) | VAF 198/328 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV52510153; called by muse, mutect2, varscan2
- FCRL1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV63825084; called by muse, mutect2, varscan2
- FGD2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 185/483 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs765613237; called by muse, mutect2, varscan2
- FGF5 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56891155; called by muse, mutect2, varscan2
- FGFBP2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 133/425 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.303); catalogued as COSV52588421; called by muse, mutect2, varscan2
- FHL2 | c.25C>A p.H9N | Missense Mutation (SNP) | VAF 622/622 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs928872164; called by muse, mutect2, varscan2
- FLG | c.3538C>T p.H1180Y | Missense Mutation (SNP) | VAF 367/538 reads (68%) | SIFT tolerated (0.45); PolyPhen benign (0.329); catalogued as rs1446613420, COSV100912523; called by muse, varscan2
- FLG2 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66167667; called by muse, mutect2, varscan2
- FLT1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56728855; called by muse, mutect2, varscan2
- FMN1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 265/420 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.871); catalogued as rs1316139391; called by muse, mutect2, varscan2
- FMN2 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 170/521 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745830094, COSV100145396; called by muse, mutect2, varscan2
- FMN2 | c.4693C>G p.L1565V | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs775335880, COSV60456331; called by muse, mutect2, varscan2
- FOXN1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 330/648 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1221726877; called by muse, mutect2, varscan2
- FRMPD1 | c.363G>A p.R121= | Splice Region (SNP) | VAF 537/537 reads (100%) | catalogued as rs1384609040; called by muse, mutect2, varscan2
- FSCB | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 220/379 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs371199022; called by muse, mutect2, varscan2
- FSCB | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 217/347 reads (63%) | SIFT tolerated (0.88); PolyPhen benign (0.118); catalogued as rs1321873328, COSV61218903; called by muse, mutect2, varscan2
- GAB1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363184155; called by muse, mutect2, varscan2
- GABRB1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 204/318 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as rs1452776426, COSV54975065; called by muse, mutect2, varscan2
- GAL3ST4 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 246/594 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as COSV100385382, COSV100385498; called by muse, mutect2, varscan2
- GALNTL6 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72493826; called by muse, mutect2, varscan2
- GAP43 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 238/348 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV59343998; called by muse, mutect2, varscan2
- GAPT | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV59246662; called by muse, mutect2, varscan2
- GAREM1 | c.1798C>T p.R600* (on ENST00000269209 / NM_001242409.2; = p.R599* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 62/161 reads (39%) | catalogued as COSV52505678, COSV99331146; called by muse, mutect2, varscan2
- GCSAML | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 95/157 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, mutect2, varscan2
- GFAP | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 327/693 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.366); catalogued as COSV53650893; called by muse, mutect2, varscan2
- GGT1 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 372/380 reads (98%) | catalogued as COSV99958429; called by muse, mutect2, varscan2
- GHITM | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs371118008; called by muse, mutect2, varscan2
- GHR | c.1006T>C p.F336L | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.326); catalogued as rs750618319; called by muse, mutect2, varscan2
- GIGYF1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 418/735 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs752292257; called by muse, mutect2, varscan2
- GIN1 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs1554194092; called by muse, mutect2, varscan2
- GIT2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV58082883; called by muse, mutect2, varscan2
- GJA3 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 288/914 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs776453557; called by muse, mutect2
- GJA8 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 132/426 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1553242609, COSV53787839; called by muse, mutect2, varscan2
- GJB4 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 282/439 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs180965135, COSV100258200; called by muse, mutect2, varscan2
- GK2 | c.389T>G p.I130S | Missense Mutation (SNP) | VAF 182/269 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.217); catalogued as COSV62627476; called by muse, mutect2, varscan2
- GLI1 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 302/669 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs778898048; called by muse, mutect2, varscan2
- GLI3 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 212/519 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV67895677; called by muse, mutect2, varscan2
- GLI3 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 210/516 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as rs765034545, COSV67895679; called by muse, mutect2, varscan2
- GLIPR1L2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1353924445; called by muse, mutect2, varscan2
- GLRA3 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs1357104088, COSV56865047; called by muse, mutect2, varscan2
- GNAS | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 327/812 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV58332462; called by muse, mutect2, varscan2
- GOLGA6C | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 211/570 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1209219864; called by muse, mutect2, varscan2
- GOLGA8A | c.1760C>T p.S587F (on ENST00000432566; = p.S559F on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 261/447 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs763707733, COSV100781628; called by muse, varscan2
- GOLGA8H | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 58/487 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as rs752641133; called by muse, varscan2
- GOLGA8M | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.357); catalogued as rs1419564637; called by muse, mutect2, varscan2
- GOLGA8M | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs1299327839; called by muse, mutect2, varscan2
- GON4L | c.5395G>C p.E1799Q | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV55197956; called by muse, mutect2
- GP2 | c.1447C>T p.R483C (on ENST00000381362 / NM_001007240.3; = p.R480C on NM_001502.4) | Missense Mutation (SNP) | VAF 175/297 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs753427089, COSV56893801; called by muse, mutect2, varscan2
- GPR146 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 362/717 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52466170; called by muse, mutect2, varscan2
- GPR149 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 170/302 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374985361; called by muse, mutect2, varscan2
- GPR158 | c.3553G>A p.G1185R | Missense Mutation (SNP) | VAF 193/327 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV66284403; called by muse, mutect2, varscan2
- GPR52 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs779775199, COSV99271847; called by muse, mutect2, varscan2
- GPRIN2 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 98/637 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs782581350, COSV65400371; called by muse, mutect2, varscan2
- GREB1L | c.3761C>T p.S1254F | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.219); catalogued as rs1395232690; called by muse, mutect2, varscan2
- GRID2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs765313483; called by muse, mutect2, varscan2
- GRIK2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 103/197 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59709996; called by muse, mutect2, varscan2
- GRIN2A | c.4069C>G p.L1357V | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763809945, COSV58022666; called by muse, mutect2, varscan2
- GRM1 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 274/496 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51172606; called by muse, mutect2, varscan2
- GUCY1A2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs1205874822; called by muse, mutect2, varscan2
- HABP2 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 97/169 reads (57%) | catalogued as COSV63637166; called by muse, mutect2, varscan2
- HBA2 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs281864853; called by muse, mutect2, varscan2
- HCFC1 | c.5369C>T p.S1790F | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV60073519; called by muse, mutect2, varscan2
- HCN1 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.174); catalogued as COSV100299108, COSV57535089; called by muse, mutect2, varscan2
- HCN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV57536526; called by muse, varscan2
- HDGFL2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 190/391 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56683272; called by muse, mutect2, varscan2
- HERC1 | c.9247G>A p.D3083N | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV71249302; called by muse, mutect2, varscan2
- HGF | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 231/529 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.438); catalogued as COSV55952401, COSV99738620; called by muse, mutect2, varscan2
- HIVEP1 | c.6868C>T p.P2290S | Missense Mutation (SNP) | VAF 261/443 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs758035535, COSV101044641; called by muse, mutect2, varscan2
- HKDC1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.069); catalogued as rs1463226976, COSV100664307, COSV63576980; called by muse, mutect2, varscan2
- HMCN1 | c.4169C>T p.P1390L | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54922652; called by muse, mutect2, varscan2
- HMCN1 | c.12796C>T p.P4266S | Missense Mutation (SNP) | VAF 128/533 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV54926916, COSV99629173; called by muse, mutect2, varscan2
- HNF4A | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 283/472 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV100291758; called by muse, varscan2
- HNRNPC | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.901); catalogued as COSV60144710; called by muse, mutect2, varscan2
- HRG | c.466A>C p.K156Q | Missense Mutation (SNP) | VAF 206/363 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1417257851; called by muse, mutect2
- HRH2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1157654705; called by muse, mutect2, varscan2
- HRNR | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs544088951; called by muse, mutect2, varscan2
- HSDL1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs895351723; called by muse, mutect2, varscan2
- HTR1A | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 140/416 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs1363080615; called by muse, varscan2
- HTR3A | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 147/550 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55470969; called by muse, mutect2, varscan2
- HTR3A | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 246/342 reads (72%) | catalogued as COSV55469726; called by muse, varscan2
- HTR3C | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1373847275; called by muse, varscan2
- HYAL4 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 146/296 reads (49%) | catalogued as rs142982813; called by muse, mutect2, varscan2
- HYDIN | c.15190C>T p.R5064C | Missense Mutation (SNP) | VAF 345/500 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs768134428; called by muse, mutect2, varscan2
- HYDIN | c.6448G>A p.V2150M | Missense Mutation (SNP) | VAF 142/262 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs768546732, COSV59261041, COSV59276264; called by muse, varscan2
- IDO2 | c.296G>A p.G99E (on ENST00000389060; = p.G112E on NM_194294.2) | Missense Mutation (SNP) | VAF 362/462 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756127333; called by muse, mutect2, varscan2
- IGF2BP2 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 360/574 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.308); catalogued as COSV100649400; called by muse, mutect2, varscan2
- IGHV1-24 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 92/329 reads (28%) | catalogued as rs781857259; called by muse, mutect2, varscan2
- IGLON5 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 409/652 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260934834; called by muse, mutect2, varscan2
- IGSF1 | c.2220G>A p.M740I | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs758261526, COSV100812335; called by muse, mutect2, varscan2
- IGSF1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1249853563; called by muse, mutect2, varscan2
- IGSF22 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1441217345; called by muse, mutect2, varscan2
- IL16 | c.3749G>A p.G1250E (on ENST00000302987 / NM_172217.5; = p.G549E on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/456 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57155051; called by muse, mutect2, varscan2
- IL22RA1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 370/562 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54628010; called by muse, mutect2, varscan2
- ILF3 | c.2421C>T p.F807= | Splice Region (SNP) | VAF 73/151 reads (48%) | catalogued as rs749273093, COSV51556838; called by muse, varscan2
- IMMP2L | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1027091447, COSV104405119; called by muse, mutect2, varscan2
- IMP4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147137797; called by muse, mutect2, varscan2
- INCENP | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 467/626 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as rs867824706, COSV53914713; called by muse, mutect2, varscan2
- INSC | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 356/486 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1234110702; called by muse, mutect2, varscan2
- INSR | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57173618; called by muse, mutect2, varscan2
- IPO4 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 165/541 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99938013; called by muse, mutect2, varscan2
- IQCM | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs900365281; called by muse, mutect2, varscan2
- IQGAP1 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 238/380 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99185334; called by muse, mutect2, varscan2
- IQGAP3 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs747202672, COSV63249636; called by muse, mutect2, varscan2
- IRAK4 | c.162G>A p.R54= | Splice Region (SNP) | VAF 108/220 reads (49%) | catalogued as rs772625246; called by muse, mutect2, varscan2
- IRF2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 67/232 reads (29%) | catalogued as COSV66928371; called by muse, varscan2
- IRF7 | c.1403C>T p.P468L (on ENST00000397566; = p.P455L on NM_001572.5) | Missense Mutation (SNP) | VAF 407/555 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs370946255; called by muse, mutect2, varscan2
- IRS2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 182/595 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV65479298, COSV65480680; called by muse, mutect2, varscan2
- ITGA10 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 101/350 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1553750256; called by muse, mutect2, varscan2
- ITGB4 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 290/647 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1199155064; called by muse, mutect2, varscan2
- ITIH5 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.373); catalogued as rs1157561901; called by muse, mutect2, varscan2
- ITIH6 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs753677323; called by muse, mutect2, varscan2
- ITK | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 148/232 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475918, COSV70061653; called by muse, varscan2
- ITPR3 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 167/880 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65414386; called by muse, mutect2, varscan2
- KALRN | c.4498C>T p.L1500F | Missense Mutation (SNP) | VAF 249/419 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53764832; called by muse, mutect2, varscan2
- KALRN | c.6863C>T p.P2288L (on ENST00000360013 / NM_001024660.4; = p.P591L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 220/354 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs574388819; called by muse, mutect2, varscan2
- KCNA1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 244/584 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1273625044, COSV66837848; called by muse, mutect2, varscan2
- KCNA1 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV101230179; called by muse, mutect2, varscan2
- KCNB2 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 491/629 reads (78%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as COSV73048905; called by muse, mutect2, varscan2
- KCNC2 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 212/464 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54381104; called by muse, mutect2
- KCND3 | c.1879G>A p.G627R | Missense Mutation (SNP) | VAF 152/557 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as rs372362132; called by muse, mutect2, varscan2
- KCNH2 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 224/404 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.227); catalogued as COSV100061392; called by muse, mutect2, varscan2
- KCNH8 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 194/272 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100108413; called by muse, varscan2
- KCNJ5 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV57966740; called by muse, mutect2, varscan2
- KCNN3 | c.2209C>T p.P737S (on ENST00000618040 / NM_001204087.1; = p.P722S on NM_002249.6) | Missense Mutation (SNP) | VAF 209/323 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV55213796; called by muse, varscan2
- KCNN4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 214/332 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs138407239; called by muse, mutect2, varscan2
- KCNQ2 | c.2051G>A p.G684D (on ENST00000359125 / NM_172107.4; = p.G656D on NM_004518.6) | Missense Mutation (SNP) | VAF 235/1080 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100609835; called by muse, mutect2, varscan2
- KCNQ3 | c.2597C>T p.T866I | Missense Mutation (SNP) | VAF 331/429 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs574185551; called by muse, mutect2, varscan2
- KCNU1 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV101299456; called by muse, mutect2, varscan2
- KDF1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 139/457 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV100264569; called by muse, mutect2, varscan2
- KDM4E | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 424/536 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1007426611; called by muse, mutect2, varscan2
- KHDRBS2 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 106/587 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV99833283; called by muse, mutect2, varscan2
- KIAA0100 | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 197/440 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV66495217; called by muse, mutect2, varscan2
- KIAA0319 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 128/646 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1332933053; called by muse, mutect2, varscan2
- KIAA0825 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100434356, COSV99080475; called by muse, mutect2, varscan2
- KIAA1109 | c.13339C>T p.R4447* | Nonsense Mutation (SNP) | VAF 201/300 reads (67%) | catalogued as COSV52668087; called by muse, mutect2, varscan2
- KIAA1549 | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 183/419 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1422818314; called by muse, mutect2, varscan2
- KIF5A | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 194/420 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1398974670, COSV54059351; called by muse, varscan2
- KIF6 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 255/491 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567607290, COSV99756999; called by muse, mutect2, varscan2
- KIR3DL2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV54392058; called by muse, mutect2, varscan2
- KIR3DL2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.056); catalogued as rs772678968, COSV54394144; called by muse, mutect2, varscan2
- KLHDC8B | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 165/747 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs751013624; called by muse, mutect2, varscan2
- KLHL1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 188/280 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1466512793, COSV64769507; called by muse, mutect2, varscan2
- KLHL23 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.285); catalogued as COSV55869758; called by muse, mutect2, varscan2
- KLHL32 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 122/560 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65111804; called by muse, mutect2, varscan2
- KLHL4 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV64142788; called by muse, mutect2, varscan2
- KLHL4 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64138949, COSV64139932, COSV64144885; called by muse, mutect2, varscan2
- KLK15 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 320/455 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763136204, COSV100033077, COSV56826089; called by muse, mutect2, varscan2
- KMT2C | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554600752, COSV100074472, COSV51277484, COSV51455188; called by muse, mutect2
- KMT2D | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 278/554 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV56475694; called by muse, mutect2, varscan2
- KRTAP5-4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 244/344 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs1264604225, COSV101294421; called by muse, mutect2, varscan2
- L1CAM | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV62828337; called by muse, mutect2, varscan2
- LAMA5 | c.5008G>A p.G1670R | Missense Mutation (SNP) | VAF 784/1285 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs759428251; called by muse, mutect2, varscan2
- LATS2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV66880798; called by muse, mutect2, varscan2
- LAX1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 260/368 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65848880, COSV65850195; called by muse, varscan2
- LCN8 | c.382C>T p.R128C (on ENST00000612714 / NM_001345934.1; = p.R105C on NM_178469.3) | Missense Mutation (SNP) | VAF 331/332 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs772091181, COSV60209349; called by muse, mutect2, varscan2
- LDLRAD2 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 163/163 reads (100%) | catalogued as COSV60828315; called by muse, mutect2, varscan2
- LILRA2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 196/578 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as rs1343868068; called by muse, mutect2, varscan2
- LMNTD2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 178/813 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1212389087, COSV99530880; called by muse, mutect2, varscan2
- LMO7 | c.1783C>T p.L595F (on ENST00000357063; = p.L325F on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/218 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765946755; called by muse, mutect2, varscan2
- LRFN1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 354/588 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs1181344561, COSV99953388; called by muse, mutect2, varscan2
- LRIT2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 246/367 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs956624811; called by muse, varscan2
- LRP1 | c.7739C>T p.S2580F | Missense Mutation (SNP) | VAF 265/544 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV54518188; called by muse, varscan2
- LRP1B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs145092192, COSV67197624, COSV67249343; called by muse, mutect2, varscan2
- LRRC30 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 240/378 reads (63%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs868821577, COSV67302280; called by muse, mutect2, varscan2
- LRRC30 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 239/375 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs757903807, COSV67301519, COSV67301867; called by muse, mutect2, varscan2
- LRRC3B | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 354/492 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1486737127, COSV101185666, COSV101186084; called by muse, mutect2, varscan2
- LRRC53 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 173/383 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1371202555; called by muse, mutect2, varscan2
- LRRIQ1 | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV67827589; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRN4 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 140/1077 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.033); catalogued as rs144964953; called by muse, mutect2, varscan2
- LY96 | c.204G>A p.R68= | Splice Region (SNP) | VAF 40/171 reads (23%) | catalogued as COSV53026179; called by muse, mutect2, varscan2
- MAEA | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 105/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53264606; called by muse, mutect2, varscan2
- MAEL | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 232/368 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs868123907; called by muse, mutect2, varscan2
- MAGEC2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV56001522; called by muse, mutect2, varscan2
- MAGI3 | c.1965A>G p.G655= | Splice Region (SNP) | VAF 57/186 reads (31%) | catalogued as rs955695074; called by muse, mutect2, varscan2
- MAJIN | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57262422, COSV57262580; called by muse, mutect2, varscan2
- MALRD1 | c.5584C>T p.P1862S | Missense Mutation (SNP) | VAF 203/322 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV65971607; called by muse, mutect2, varscan2
- MAML1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 328/505 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1265495106; called by muse, mutect2, varscan2
- MAN2A1 | c.2425C>T p.L809F | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99811100; called by muse, mutect2, varscan2
- MAP1B | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99702675; called by muse, mutect2, varscan2
- MAP3K1 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 177/275 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as rs774985330; called by muse, mutect2, varscan2
- MAPK1IP1L | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 189/473 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.654); catalogued as rs1185627987, COSV67106437; called by muse, mutect2, varscan2
- MAPK9 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 198/314 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV58125054; called by muse, varscan2
- MAST3 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 199/408 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs906101465; called by muse, mutect2, varscan2
- MAST4 | c.923C>T p.S308F (on ENST00000403625 / NM_001164664.2; = p.S119F on NM_015183.3) | Missense Mutation (SNP) | VAF 123/182 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141458; called by muse, mutect2, varscan2
- MATN4 | c.1535G>A p.R512H (on ENST00000372754; = p.R471H on NM_003833.4) | Missense Mutation (SNP) | VAF 116/599 reads (19%) | PolyPhen probably damaging (0.976); catalogued as rs778280289, COSV61352191; called by muse, mutect2, varscan2
- MBD5 | c.2593C>T p.L865F | Missense Mutation (SNP) | VAF 353/355 reads (99%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV101289931; called by muse, mutect2, varscan2
- MCTP1 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs370579973; called by muse, mutect2, varscan2
- MDGA2 | c.2259G>T p.W753C (on ENST00000399232 / NM_001113498.2; = p.W455C on NM_182830.4) | Missense Mutation (SNP) | VAF 112/183 reads (61%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100638709; called by muse, mutect2, varscan2
- MEGF10 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs775952846; called by muse, mutect2, varscan2
- MEIS2 | c.682C>T p.H228Y (on ENST00000561208 / NM_170675.5; = p.H215Y on NM_002399.3) | Missense Mutation (SNP) | VAF 189/310 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as rs147874392; called by muse, mutect2, varscan2
- MEN1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 269/394 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as CM994387, COSV99580526; called by muse, varscan2
- MEP1B | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1288958310, COSV99329057; called by muse, mutect2, varscan2
- METTL3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 187/291 reads (64%) | SIFT tolerated (0.97); PolyPhen benign (0.245); catalogued as rs764934314; called by muse, mutect2, varscan2
- MEX3B | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 392/580 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs373501308; called by muse, mutect2, varscan2
- MFSD8 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1314690167; called by muse, mutect2, varscan2
- MIA2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 92/152 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs185291670, COSV54494523; called by muse, mutect2, varscan2
- MINDY4 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 308/600 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54678465; called by muse, mutect2, varscan2
- MLIP | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 132/637 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV51438111; called by muse, mutect2, varscan2
- MMP3 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 241/321 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555005557, COSV55406188; called by muse, mutect2, varscan2
- MMP8 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV52633422; called by muse, mutect2
- MMRN1 | c.2734C>T p.H912Y | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53336009; called by muse, mutect2, varscan2
- MPZL1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs150906954, COSV63257040; called by muse, mutect2, varscan2
- MROH2B | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 107/164 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs1007254835; called by muse, mutect2, varscan2
- MROH7 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 163/406 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747900802, COSV64887264; called by muse, mutect2, varscan2
- MRPS30 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753072820; called by muse, mutect2, varscan2
- MS4A8 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 156/240 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55756257; called by muse, mutect2, varscan2
- MSR1 | c.1301G>A p.W434* | Nonsense Mutation (SNP) | VAF 84/426 reads (20%) | catalogued as rs771088951; called by muse, varscan2
- MSRB3 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 238/455 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as rs1160327177, COSV57594686; called by muse, mutect2, varscan2
- MSTN | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 219/220 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs753241714, COSV53620696; called by muse, mutect2, varscan2
- MTERF3 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1411861939; called by muse, mutect2, varscan2
- MTMR4 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 258/543 reads (48%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs774873044; called by muse, mutect2, varscan2
- MTMR6 | c.1747del p.R583Efs*3 | Frame Shift Del (DEL) | VAF 272/529 reads (51%) | catalogued as COSV67807735; called by mutect2, pindel, varscan2
- MUC15 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 287/402 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55554836; called by muse, mutect2, varscan2
- MUC16 | c.35332C>T p.P11778S | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV67503035; called by muse, mutect2, varscan2
- MUC16 | c.16589C>T p.S5530F | Missense Mutation (SNP) | VAF 132/264 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV67466958, COSV67478526; called by muse, mutect2, varscan2
- MUC16 | c.13306C>T p.P4436S | Missense Mutation (SNP) | VAF 129/250 reads (52%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.239); catalogued as COSV67456130; called by muse, mutect2, varscan2
- MUC16 | c.4957G>A p.G1653R | Missense Mutation (SNP) | VAF 146/284 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as rs1483575555, COSV101199457; called by muse, varscan2
- MUC17 | c.8006G>A p.G2669E | Missense Mutation (SNP) | VAF 289/576 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs1280127452, COSV60281634, COSV60283041; called by muse, mutect2, varscan2
- MUC3A | c.8027C>T p.S2676F | Missense Mutation (SNP) | VAF 230/852 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV60221998; called by muse, mutect2
- MUC5B | c.7706C>T p.S2569F | Missense Mutation (SNP) | VAF 68/1364 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.353); catalogued as COSV71590617; called by muse, mutect2
- MUC5B | c.7946C>T p.P2649L | Missense Mutation (SNP) | VAF 761/1038 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV71591317; called by muse, mutect2, varscan2
- MUC5B | c.9064C>T p.P3022S | Missense Mutation (SNP) | VAF 659/885 reads (74%) | SIFT tolerated (0.76); PolyPhen benign (0.066); catalogued as rs764292695; called by muse, mutect2, varscan2
- MUC7 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 162/610 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.148); catalogued as rs867099745; called by muse, varscan2
- MX1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs541890706; called by muse, mutect2, varscan2
- MX2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 339/721 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747716429, COSV58096778; called by muse, mutect2, varscan2
- MXD4 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 340/529 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs780860666; called by muse, varscan2
- MXRA5 | c.7660G>A p.A2554T | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs1388114279; called by muse, mutect2, varscan2
- MXRA5 | c.5948C>T p.S1983F | Missense Mutation (SNP) | VAF 339/339 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277492063, COSV54239198; called by muse, mutect2, varscan2
- MYBBP1A | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 286/592 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs758603657, COSV54601648; called by muse, mutect2, varscan2
- MYH1 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 195/355 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1169015833; called by muse, mutect2, varscan2
- MYH10 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 151/325 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1353401334, COSV52600620; called by muse, mutect2, varscan2
- MYH13 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 255/568 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99353393; called by muse, mutect2, varscan2
- MYH13 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 495/496 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs780968912, COSV52822339; called by muse, mutect2, varscan2
- MYH14 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1393112947; called by muse, mutect2, varscan2
- MYH7 | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 226/449 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs794727410, CM115869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL9 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 279/740 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54072685; called by muse, mutect2, varscan2
- MYO16 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99194989; called by muse, mutect2, varscan2
- MYO3B | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 308/309 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs746744711, COSV58711463; called by muse, mutect2, varscan2
- MYO7A | c.2642G>C p.R881P | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV68687148; called by muse, mutect2, varscan2
- MYOM2 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 132/606 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754915537, COSV50709087; called by muse, mutect2, varscan2
- MYOZ3 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs150546422; called by muse, varscan2
- MYT1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 117/700 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100114435; called by muse, mutect2, varscan2
- NBPF11 | c.1089C>T p.L363= | Splice Region (SNP) | VAF 116/348 reads (33%) | catalogued as rs78261742; called by muse, mutect2, varscan2
- NCOR2 | c.6320C>T p.P2107L | Missense Mutation (SNP) | VAF 427/919 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1291081651; called by muse, mutect2, varscan2
- NEK10 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 402/523 reads (77%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1450164267; called by muse, mutect2, varscan2
- NEUROD4 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV54470365; called by muse, mutect2, varscan2
- NEXMIF | c.2786C>T p.T929I | Missense Mutation (SNP) | VAF 301/301 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs370164571; called by muse, mutect2, varscan2
- NFATC2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 247/634 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771040521, COSV101043875; called by muse, mutect2, varscan2
- NFKB2 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 138/208 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99503043; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 140/815 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, varscan2
- NFKBIZ | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 418/625 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs753252484; called by muse, mutect2, varscan2
- NGEF | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 300/300 reads (100%) | catalogued as COSV50939939; called by muse, mutect2, varscan2
- NHSL1 | c.3152C>T p.S1051F | Missense Mutation (SNP) | VAF 453/735 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1205727853; called by muse, mutect2, varscan2
- NID2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 252/434 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53496573; called by muse, mutect2, varscan2
- NKAIN2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63658994; called by muse, mutect2, varscan2
- NLGN1 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 122/208 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64341130; called by muse, mutect2, varscan2
- NLRP11 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 226/345 reads (66%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs769380246; called by muse, mutect2, varscan2
- NLRP11 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 109/181 reads (60%) | catalogued as COSV64086734; called by muse, mutect2, varscan2
- NME8 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1485219232, COSV52251548; called by muse, mutect2, varscan2
- NMRK2 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs149329333, COSV51456845; called by muse, mutect2, varscan2
- NMT2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 149/218 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1333352963, COSV65382603; called by muse, mutect2, varscan2
- NOTCH1 | c.5308C>T p.P1770S | Missense Mutation (SNP) | VAF 562/562 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53028602, COSV53070146; called by muse, mutect2, varscan2
- NOX3 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 370/654 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750663085, COSV50154109, COSV99343503; called by muse, mutect2, varscan2
- NPSR1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 227/419 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV62204314; called by muse, mutect2, varscan2
- NPTXR | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 716/717 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773964723, COSV60728166; called by muse, mutect2, varscan2
- NR1H4 | c.215C>T p.S72F (on ENST00000551379 / NM_001206993.2; = p.S62F on NM_005123.4) | Missense Mutation (SNP) | VAF 198/449 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs868079755, COSV51849579; called by muse, mutect2, varscan2
- NRCAM | c.2527G>A p.D843N (on ENST00000379028 / NM_001371124.1; = p.D827N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/334 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV61036689; called by muse, mutect2, varscan2
- NRG3 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 127/198 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV64544359; called by muse, mutect2, varscan2
- NRIP1 | c.3025C>A p.P1009T | Missense Mutation (SNP) | VAF 211/430 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs1358255264, COSV59658486; called by muse, mutect2, varscan2
- NRXN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 503/663 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1047822230, COSV99634709; called by muse, mutect2, varscan2
- NSG2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 139/229 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57460443; called by muse, mutect2, varscan2
- NT5C1A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 311/470 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763524745, COSV52494659; called by muse, mutect2, varscan2
- NTRK1 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 258/490 reads (53%) | catalogued as rs866270701; called by muse, varscan2
- NUDT9 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1181625088; called by muse, mutect2, varscan2
- OBI1 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs1478260095; called by muse, mutect2, varscan2
- OBSCN | c.1964G>A p.S655N | Missense Mutation (SNP) | VAF 584/788 reads (74%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as rs758968383; called by muse, mutect2, varscan2
- OBSCN | c.14851G>A p.D4951N | Missense Mutation (SNP) | VAF 545/744 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99486623; called by muse, mutect2, varscan2
- OPCML | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 318/425 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV59450642; called by muse, mutect2, varscan2
- OPHN1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 75/75 reads (100%) | catalogued as COSV100830860, COSV62784695; called by muse, mutect2, varscan2
- OR10A3 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 367/511 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375829095, COSV62459852; called by muse, mutect2, varscan2
- OR10AG1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 285/396 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs370375009, COSV100400000; called by muse, mutect2, varscan2
- OR10T2 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV57781363; called by muse, mutect2, varscan2
- OR2A12 | c.513A>T p.Q171H | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV68821069; called by muse, mutect2, varscan2
- OR2G3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 198/295 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914697985; called by muse, mutect2, varscan2
- OR2L3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100741913, COSV63454624; called by muse, varscan2
- OR2M4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 187/307 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100141368, COSV100141577; called by muse, mutect2, varscan2
- OR2T1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 419/647 reads (65%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs141385938, COSV63542173, COSV63542511; called by muse, mutect2, varscan2
- OR2T33 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV100532324; called by muse, mutect2, varscan2
- OR2T35 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1009534401; called by muse, mutect2
- OR2T35 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV58086474; called by muse, mutect2
- OR2W1 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 217/376 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs1312141759; called by muse, mutect2, varscan2
- OR4A16 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV100125043, COSV59044247; called by muse, mutect2
- OR4C6 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs139660252, COSV58603441, COSV58605175; called by muse, mutect2, varscan2
- OR4C6 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.181); catalogued as COSV58606229; called by muse, mutect2, varscan2
- OR4D1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 244/502 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99273994; called by muse, mutect2
- OR51A7 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752821821, COSV100834683, COSV63788460; called by muse, mutect2, varscan2
- OR52N4 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100421772; called by muse, mutect2, varscan2
- OR56A4 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 112/505 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58110394; called by muse, mutect2, varscan2
- OR5AR1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 231/320 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57255437; called by muse, mutect2, varscan2
- OR6C65 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.092); catalogued as COSV101110182, COSV65569065; called by muse, mutect2, varscan2
- OR6K3 | c.52G>A p.E18K (on ENST00000368146; = p.E2K on NM_001005327.2) | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100933839; called by muse, mutect2, varscan2
- OR6K6 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs779056999, COSV63744109; called by mutect2, varscan2
- OR6P1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1301370490; called by muse, mutect2, varscan2
- OR6Y1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56928377, COSV56929347; called by muse, mutect2, varscan2
- OR7A5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as COSV59234280; called by muse, varscan2
- OR8B2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 193/380 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100899383, COSV66664152; called by muse, varscan2
- OR8H1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 118/534 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs115524514; called by muse, mutect2, varscan2
- OR8K5 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 97/456 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs371957978, COSV57887956; called by muse, mutect2, varscan2
- OTOA | c.3392G>A p.G1131E (on ENST00000286149; = p.G1117E on NM_144672.4) | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1226156217; called by muse, mutect2, varscan2
- OTOGL | c.3085G>A p.E1029K (on ENST00000547103; = p.E1020K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV72007498; called by muse, mutect2, varscan2
- OTOL1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1265085056; called by muse, mutect2, varscan2
- OTP | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 270/404 reads (67%) | catalogued as COSV100119934; called by muse, mutect2, varscan2
- OXNAD1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV99551461; called by muse, mutect2, varscan2
- OXT | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 391/1230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54131662; called by muse, mutect2, varscan2
- P2RX6 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 535/535 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53036635; called by muse, mutect2, varscan2
- PAK6 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 137/464 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); catalogued as COSV53047437; called by muse, mutect2, varscan2
- PANK4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 410/647 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65865529; called by muse, mutect2, varscan2
- PARD3 | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 257/394 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs552767746; called by muse, mutect2, varscan2
- PAX2 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 174/613 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62291007; called by muse, mutect2, varscan2
- PCDH17 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 233/675 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs769778384, COSV100931563, COSV64976726; called by muse, mutect2, varscan2
- PCDH8 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 476/756 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.268); catalogued as COSV58814296; called by muse, mutect2
- PCDHA1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.197); catalogued as rs143010606, COSV65373538; called by muse, mutect2, varscan2
- PCDHA10 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 215/343 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56475118; called by muse, mutect2, varscan2
- PCDHA10 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV56497940; called by muse, mutect2, varscan2
- PCDHA12 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 389/583 reads (67%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.433); catalogued as COSV56531239; called by muse, mutect2, varscan2
- PCDHA9 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 283/448 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV65323835; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 131/372 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- PCDHB3 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 216/849 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs782378096, COSV50590519; called by muse, mutect2, varscan2
- PCDHB4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52023523, COSV52024096; called by muse, mutect2, varscan2
- PCDHGA1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV100966010; called by muse, mutect2, varscan2
- PCDHGA2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53998896; called by muse, mutect2, varscan2
- PCDHGA2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53905586; called by muse, mutect2, varscan2
- PCDHGA6 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 308/483 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1177848611; called by muse, mutect2, varscan2
- PCDHGA9 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1415465011, COSV53911980; called by muse, mutect2, varscan2
- PCDHGB5 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53922724; called by muse, mutect2, varscan2
- PCLO | c.8648G>A p.W2883* | Nonsense Mutation (SNP) | VAF 248/446 reads (56%) | catalogued as COSV61619117; called by muse, mutect2, varscan2
- PCLO | c.3391G>T p.G1131* | Nonsense Mutation (SNP) | VAF 214/506 reads (42%) | catalogued as COSV100436374; called by muse, mutect2, varscan2
- PCLO | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 322/562 reads (57%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.036); catalogued as COSV61613157; called by muse, mutect2, varscan2
- PCOLCE2 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55999099; called by muse, mutect2, varscan2
- PCSK7 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 304/829 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312741778; called by muse, mutect2, varscan2
- PDE10A | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63106187; called by muse, mutect2, varscan2
- PDE10A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV63106219; called by muse, mutect2, varscan2
- PDE11A | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 319/320 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1467758518, COSV99610864; called by muse, mutect2, varscan2
- PDE8B | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 316/485 reads (65%) | catalogued as COSV53737897; called by muse, mutect2, varscan2
- PDGFRL | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 219/581 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs138541368; called by muse, mutect2, varscan2
- PDHX | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773340684; called by muse, mutect2, varscan2
- PDILT | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 133/393 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.87); catalogued as COSV56704036; called by muse, mutect2, varscan2
- PDLIM4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 158/481 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223503833; called by muse, mutect2, varscan2
- PDZD8 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV57824916; called by muse, mutect2, varscan2
- PEG3 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99690679; called by muse, mutect2, varscan2
- PEG3 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 221/360 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55638839; called by muse, mutect2, varscan2
- PEG3 | c.771C>T p.L257= | Splice Region (SNP) | VAF 82/279 reads (29%) | catalogued as rs369295065; called by muse, varscan2
- PERM1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 125/422 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1343963140; called by muse, mutect2, varscan2
- PGBD5 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 94/278 reads (34%) | catalogued as rs149364273; called by muse, mutect2, varscan2
- PGM2L1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV53349397; called by muse, mutect2, varscan2
- PGR | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 33/191 reads (17%) | catalogued as rs1209629034, COSV54798528, COSV54801881; called by muse, mutect2
- PHACTR4 | c.209C>T p.S70F (on ENST00000373839 / NM_001350159.2; = p.S80F on NM_023923.4) | Missense Mutation (SNP) | VAF 122/203 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65785060; called by muse, mutect2, varscan2
- PIDD1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 120/576 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1249405531; called by muse, varscan2
- PIK3CA | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 127/214 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as rs3865687, COSV99836409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIP5K1C | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 150/301 reads (50%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1267600243, COSV58950876; called by muse, mutect2, varscan2
- PKHD1 | c.7237C>T p.R2413C | Missense Mutation (SNP) | VAF 156/280 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as rs553534988, COSV61882709; called by muse, mutect2, varscan2
- PKHD1L1 | c.9065C>T p.P3022L | Missense Mutation (SNP) | VAF 272/370 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs1204171745; called by muse, mutect2
- PLA2G15 | c.129C>T p.V43= | Splice Region (SNP) | VAF 78/241 reads (32%) | catalogued as COSV54722242; called by muse, mutect2, varscan2
- PLA2G4D | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs146924938; called by muse, mutect2, varscan2
- PLCB4 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 152/501 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53802578; called by muse, mutect2, varscan2
- PLCB4 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 152/503 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53801544, COSV53804867; called by muse, mutect2, varscan2
- PLCE1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV53345182; called by muse, mutect2, varscan2
- PLCE1 | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 339/528 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1234627666, COSV99595639; called by muse, mutect2, varscan2
- PLCL2 | c.454G>A p.V152I (on ENST00000615277 / NM_001144382.2; = p.V26I on NM_015184.5) | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs141837634, COSV101196677; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 108/379 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746073648, COSV60610978, COSV60618210; called by muse, mutect2, varscan2
- PLEKHA4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 352/547 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV54364795; called by muse, mutect2, varscan2
- PLEKHN1 | c.727C>T p.P243S (on ENST00000379409; = p.P203S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 272/407 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); catalogued as rs1469260222; called by muse, mutect2, varscan2
- PLG | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 71/425 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs896552124; called by muse, mutect2, varscan2
- PLG | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 185/367 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57516306, COSV57521797; called by muse, mutect2, varscan2
- PLOD2 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51470449; called by muse, mutect2, varscan2
- PLPPR2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 155/347 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV99264662; called by muse, mutect2, varscan2
- PLSCR4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 195/312 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149266233, COSV61608834; called by muse, mutect2, varscan2
- PNPLA2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 142/621 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1328957272; called by muse, mutect2, varscan2
- POLR1E | c.682C>T p.R228C (on ENST00000377792 / NM_001282766.1; = p.R166C on NM_022490.4) | Missense Mutation (SNP) | VAF 573/573 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs371060869; called by muse, mutect2, varscan2
- POM121L2 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 351/569 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs764559413; called by muse, mutect2, varscan2
- POMGNT2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 185/823 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.355); catalogued as COSV60955130; called by muse, mutect2, varscan2
- POPDC3 | c.333G>T p.L111F | Missense Mutation (SNP) | VAF 121/599 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs774129345, COSV99633951; called by muse, mutect2
- PPARGC1B | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 411/636 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs369499422; called by muse, mutect2, varscan2
- PPEF2 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99714645; called by muse, mutect2, varscan2
- PPFIA3 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 189/679 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1346423785; called by muse, mutect2, varscan2
- PPIL2 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 401/402 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750495789; called by muse, mutect2, varscan2
- PPIP5K2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58605632; called by muse, mutect2, varscan2
- PPP1R15B | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 123/550 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764039638; called by muse, mutect2, varscan2
- PPP1R3A | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52877297; called by muse, mutect2, varscan2
- PPRC1 | c.3673G>A p.V1225M | Missense Mutation (SNP) | VAF 218/343 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs530226906; called by muse, mutect2, varscan2
- PPRC1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 291/447 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1273824903, COSV99531697; called by muse, mutect2, varscan2
- PRDM5 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 113/182 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99311176; called by muse, mutect2, varscan2
- PRDM9 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs1251212545, COSV99691262; called by muse, mutect2, varscan2
- PREP | c.1436C>A p.P479H (on ENST00000369110; = p.P545H on NM_002726.5) | Missense Mutation (SNP) | VAF 179/469 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV64872364; called by muse, mutect2, varscan2
- PRH2 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 331/1180 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV67171947; called by muse, mutect2, varscan2
- PRKAB2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 90/346 reads (26%) | catalogued as rs782092808; called by muse, mutect2, varscan2
- PRKCA | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 164/377 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV52592035; called by mutect2, varscan2
- PRPF31 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 178/570 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV58085846; called by muse, mutect2, varscan2
- PRR15 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 462/999 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs781290728; called by muse, mutect2, varscan2
- PRR19 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 219/596 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs758679667; called by muse, mutect2, varscan2
- PRR33 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 568/801 reads (71%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs1054375753; called by muse, mutect2, varscan2
- PRRC2C | c.3202C>A p.Q1068K (on ENST00000367742; = p.Q1066K on NM_015172.4) | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.042); catalogued as COSV58900228; called by muse, mutect2, varscan2
- PRSS51 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 101/481 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs1352601142; called by muse, mutect2, varscan2
- PSMB7 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 324/327 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV52333619; called by muse, mutect2, varscan2
- PSMG3 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 310/692 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs993790978; called by muse, mutect2, varscan2
- PTBP3 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs267602089, COSV52956512; called by muse, mutect2, varscan2
- PTF1A | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 158/497 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1286923303, COSV64735185; called by muse, mutect2, varscan2
- PTGIR | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 433/640 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs772813201; called by muse, varscan2
- PTGIS | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 346/1004 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV54839324; called by muse, mutect2, varscan2
- PTPRN | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 282/282 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs754715202, COSV55352616; called by muse, mutect2, varscan2
- PTPRQ | c.1383A>T p.K461N (on ENST00000616559; = p.K419N on NM_001145026.2) | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.12); catalogued as COSV57043016; called by muse, varscan2
- PTPRS | c.5534C>A p.P1845Q | Missense Mutation (SNP) | VAF 124/253 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53617407; called by muse, mutect2, varscan2
- PTPRT | c.4156G>A p.G1386R | Missense Mutation (SNP) | VAF 85/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62007849; called by muse, mutect2, varscan2
- PTX4 | c.695G>A p.G232E (on ENST00000447419 / NM_001328608.2; = p.G227E on NM_001013658.1) | Missense Mutation (SNP) | VAF 416/606 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs867227900, COSV53517830; called by muse, mutect2, varscan2
- PUM1 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 265/518 reads (51%) | catalogued as rs1205053435, COSV57084513; called by muse, mutect2, varscan2
- PUM1 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 215/449 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.999); catalogued as rs1261659584; called by muse, mutect2, varscan2
- PWWP3B | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 385/386 reads (100%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs751709228, COSV100531470, COSV61799189; called by muse, mutect2, varscan2
- PXDC1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 301/558 reads (54%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs765788763; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 420/554 reads (76%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by mutect2, varscan2
- QRICH1 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100455092, COSV58707537; called by muse, mutect2, varscan2
- QRICH1 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 420/546 reads (77%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as rs1421297629; called by muse, mutect2, varscan2
- QRICH2 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 204/411 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs779027627, COSV53153955, COSV53156607; called by muse, mutect2, varscan2
- QTRT2 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs772074588; called by muse, mutect2, varscan2
- R3HDM4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 207/402 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs1243797426, COSV64292714, COSV64292807; called by muse, mutect2, varscan2
- RAB4B | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 243/367 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1377592404; called by muse, mutect2, varscan2
- RAI2 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 385/386 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV58964204; called by muse, mutect2, varscan2
- RALYL | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 446/566 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567857079, COSV72818303; called by muse, mutect2, varscan2
- RALYL | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 342/434 reads (79%) | SIFT tolerated (0.37); PolyPhen benign (0.189); catalogued as rs766059077, COSV101569346; called by muse, mutect2, varscan2
- RANBP2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 121/128 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372617079; called by muse, mutect2, varscan2
- RASGRP2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs199706727, COSV62449262; called by muse, mutect2, varscan2
- RASL12 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 194/566 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs779313984; called by muse, mutect2, varscan2
- RAVER2 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 228/467 reads (49%) | catalogued as COSV53808006; called by muse, varscan2
- RBMXL3 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 432/440 reads (98%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1556558910; called by muse, mutect2, varscan2
- RBP3 | c.2872G>A p.G958R | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs782468363; called by muse, mutect2, varscan2
- RCSD1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 268/392 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV63257724; called by muse, mutect2, varscan2
- RELA | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 114/456 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1422039715; called by muse, varscan2
- RELN | c.7506G>A p.W2502* | Nonsense Mutation (SNP) | VAF 127/328 reads (39%) | catalogued as COSV100633305; called by muse, mutect2, varscan2
- RELN | c.5489G>A p.G1830D | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1255854701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.4905G>A p.M1635I | Missense Mutation (SNP) | VAF 144/271 reads (53%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.675); catalogued as rs1423049871; called by muse, mutect2, varscan2
- RFFL | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 216/483 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs781337074, COSV52071344; called by muse, mutect2, varscan2
- RFX6 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 113/654 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs866689448, COSV60586918; called by muse, mutect2, varscan2
- RHBDF1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 214/362 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs763943277; called by muse, mutect2, varscan2
- RIT2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56304827; called by muse, mutect2, varscan2
- RNF157 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 181/368 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs896385751; called by muse, mutect2, varscan2
- ROBO4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1214170553, COSV60621469; called by muse, mutect2, varscan2
2,600 further variants in this file (1,419 protein-altering or splice-affecting, 1,044 silent, 137 other) are not listed here.
